Somatic mutation profile of tumor specimen TCGA-CL-5917-01A (aliquot TCGA-CL-5917-01A-11D-1657-10) from TCGA case TCGA-CL-5917, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-CL-5917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7bee798-aebd-4680-9b10-c4d43d1e5a0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CL-5917-10A (Blood Derived Normal), aliquot TCGA-CL-5917-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dec7424a-863e-4269-80ce-945358f5f550

The open-access MAF lists 88 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 54, Silent 22, Nonsense Mutation 6, In Frame Del 2, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 36/77 reads (47%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 82/168 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 52/62 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3679C>T p.R1227C (on ENST00000326724 / NM_001080395.3; = p.R1124C on NM_004920.2) | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs374195702; called by muse, mutect2, varscan2
- ABCA9 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 140/166 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs754353946, COSV60625694; called by muse, mutect2, varscan2
- APC | c.4248del p.I1417Lfs*2 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | catalogued as CD972011, COSV57334672; called by mutect2, pindel, varscan2
- ARFGEF2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 41/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568712014, COSV64212675; called by muse, mutect2, varscan2
- ATM | c.8435C>A p.S2812Y | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as CD162053, COSV53734098; called by muse, mutect2, varscan2
- B3GAT1 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV100437760; called by muse, mutect2
- BOD1L1 | c.5948C>A p.A1983E | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV50015735; called by muse, mutect2, varscan2
- CAPN5 | c.2005G>A p.V669M (on ENST00000456580; = p.V629M on NM_004055.5) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs781990034, COSV53688309; called by muse, mutect2, varscan2
- CARMIL3 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs757549421, COSV57726729; called by muse, mutect2, varscan2
- CDH8 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs764705484, COSV54870776; called by muse, mutect2, varscan2
- CFAP46 | c.6905C>T p.S2302L | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.65); catalogued as rs145659759; called by muse, mutect2, varscan2
- CMKLR1 | c.298G>A p.A100T (on ENST00000312143 / NM_001142344.2; = p.A98T on NM_004072.3) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs370635582, COSV56438737; called by muse, mutect2, varscan2
- COL4A2 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433036701, COSV100847269; called by muse, mutect2
- COL6A3 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs372255458; called by muse, mutect2, varscan2
- CPED1 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 126/224 reads (56%) | catalogued as COSV59997510; called by muse, mutect2, varscan2
- CPO | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 90/327 reads (28%) | catalogued as COSV55939998; called by muse, mutect2, varscan2
- DHX35 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52670754; called by muse, mutect2, varscan2
- DNMT3B | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.217); catalogued as rs762537914, COSV52418830; called by muse, mutect2, varscan2
- FKBP1A | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 80/98 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101098379, COSV67750534; called by muse, mutect2, varscan2
- FLII | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 79/93 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs200966684; called by muse, mutect2, varscan2
- FLNA | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs200673062, COSV61038114; ClinVar: likely benign; called by muse, mutect2, varscan2
- GARNL3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 259/325 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767324882, COSV59225763; called by muse, mutect2, varscan2
- GET4 | c.254T>C p.L85S | Missense Mutation (SNP) | VAF 124/216 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56254811; called by muse, mutect2, varscan2
- GPR137B | c.290_292del p.S97del | In Frame Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs751387259; called by mutect2, pindel, varscan2
- GRIA1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs754902232, COSV53619315; called by muse, mutect2, varscan2
- H1-5 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as rs200387249, COSV58900246; called by muse, mutect2, varscan2
- HIPK2 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61228141, COSV61228198; called by muse, mutect2, varscan2
- IRF8 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 128/201 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs765523642, COSV51898253; called by muse, mutect2, varscan2
- ITIH3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs192350744; called by muse, mutect2, varscan2
- KIF21A | c.3672-2A>G p.X1224_splice (on ENST00000361418 / NM_001378440.1; = p.X1211_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 67/252 reads (27%) | catalogued as COSV100735300, COSV62772227; called by muse, mutect2, varscan2
- LMTK3 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as rs1285726935, COSV54313043; called by muse, mutect2
- LZTS1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1178676184, COSV56117084; called by muse, mutect2, varscan2
- MARCHF11 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs781465967, COSV100198122, COSV60125763; called by muse, mutect2, varscan2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2, varscan2
- PAPPA | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 101/234 reads (43%) | catalogued as rs1301505834, COSV60284600; called by muse, mutect2, varscan2
- PCDHGB7 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53960386; called by muse, mutect2, varscan2
- PFKFB1 | c.228T>A p.F76L | Missense Mutation (SNP) | VAF 109/224 reads (49%) | PolyPhen probably damaging (0.996); catalogued as COSV66628511; called by muse, mutect2, varscan2
- PIGK | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 128/158 reads (81%) | catalogued as COSV63062294; called by muse, mutect2, varscan2
- PIGP | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs1466858133, COSV61640036; called by muse, mutect2, varscan2
- PLIN4 | c.1561G>A p.V521I (on ENST00000301286; = p.V536I on NM_001367868.2) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs201981653; called by muse, mutect2, varscan2
- PLXNB3 | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100737210; called by muse, mutect2, varscan2
- RAP1GDS1 | c.109A>T p.N37Y (on ENST00000408927 / NM_001100427.2; = p.N38Y on NM_021159.5) | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV52787596; called by muse, mutect2, varscan2
- REEP1 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV51256995; called by muse, mutect2, varscan2
- RP1 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55118096; called by muse, mutect2, varscan2
- SGIP1 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV52770330; called by muse, mutect2, varscan2
- SLC1A1 | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV52053642; called by muse, mutect2, varscan2
- SLC26A4 | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV55917074, COSV55920696; called by muse, mutect2, varscan2
- SLC36A2 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs766086527, COSV58862540; called by muse, mutect2, varscan2
- SLCO1B3 | c.1682+2dup p.X561_splice | Splice Site (INS) | VAF 84/299 reads (28%) | catalogued as rs1405510880; called by mutect2, pindel, varscan2
- SPOCK3 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as rs1453460822, COSV100692231; called by muse, mutect2, varscan2
- TBC1D25 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65123835; called by muse, mutect2, varscan2
- TBXT | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV51617756; called by muse, mutect2, varscan2
- TENM1 | c.3687G>T p.L1229F | Missense Mutation (SNP) | VAF 114/235 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as COSV64433355; called by muse, mutect2, varscan2
- TNS1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 84/95 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370385101; called by muse, mutect2, varscan2
- TRIM42 | c.2024A>T p.Y675F | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53883451; called by muse, mutect2, varscan2
- U2AF2 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50038179; called by muse, mutect2, varscan2
- ZFR | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs1427030825, COSV54053665; called by muse, mutect2
- ZNF229 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as rs370451566; called by muse, mutect2, varscan2
- ZNF671 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV58053113; called by muse, mutect2, varscan2
- ZSCAN1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56604954; called by muse, varscan2
- DCN | c.497_502del p.R166_V168delinsL | In Frame Del (DEL) | VAF 28/247 reads (11%) | called by pindel*, varscan2
- POLA1 | c.2817dup p.L940Sfs*4 | Frame Shift Ins (INS) | VAF 48/369 reads (13%) | called by mutect2, pindel, varscan2
- AFM | c.444C>T p.C148= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs1198226554, COSV56920385, COSV56921980; called by muse, mutect2, varscan2
- DAB2IP | c.1497G>A p.S499= (on ENST00000408936; = p.S471= on NM_032552.3) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs371966536; called by mutect2, varscan2
- DMKN | c.1071T>C p.F357= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV60086717; called by muse, mutect2, varscan2
- DOK7 | c.1416C>T p.G472= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs769793776, COSV60772405; called by muse, mutect2, varscan2
- DYSF | c.1176G>A p.P392= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs544769503, COSV99245123; called by muse, mutect2, varscan2
- FAM200A | c.654C>T p.T218= | Silent (SNP) | VAF 162/576 reads (28%) | catalogued as rs778073812, COSV68808756; called by muse, mutect2, varscan2
- FAM98A | c.825G>A p.L275= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV53210495; called by muse, mutect2, varscan2
- HARS2 | c.171C>T p.I57= | Silent (SNP) | VAF 76/170 reads (45%) | catalogued as rs1204831145, COSV56907055; called by muse, mutect2, varscan2
- KCNT1 | c.3207C>T p.G1069= (on ENST00000488444; = p.G1095= on NM_020822.3) | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs778877333, COSV53699323; called by muse, mutect2, varscan2
- MAST4 | c.6963C>T p.S2321= (on ENST00000403625 / NM_001164664.2; = p.S2132= on NM_015183.3) | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as rs759964578, COSV55122858; called by muse, mutect2, varscan2
- OIT3 | c.948C>T p.V316= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs759790374, COSV61826288; called by muse, mutect2, varscan2
- PCYT1B | c.765T>C p.N255= | Silent (SNP) | VAF 422/808 reads (52%) | catalogued as COSV100770524; called by muse, mutect2, varscan2
- PDZRN4 | c.1437C>T p.I479= (on ENST00000402685 / NM_001164595.2; = p.I221= on NM_013377.4) | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as COSV54203465; called by muse, mutect2, varscan2
- RFC4 | c.1044C>T p.L348= | Silent (SNP) | VAF 109/165 reads (66%) | catalogued as COSV56217090, COSV99961279; called by muse, mutect2, varscan2
- SERPINA10 | c.414C>T p.P138= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs770457875, COSV56228536; called by muse, mutect2, varscan2
- SIPA1L1 | c.4545C>T p.H1515= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100665263; called by muse, mutect2
- SLC17A6 | c.1680G>A p.K560= | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as COSV54136980; called by muse, mutect2, varscan2
- SPTB | c.4827C>T p.S1609= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs187631599; called by muse, mutect2, varscan2
- UBQLN3 | c.471G>T p.L157= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100293436; called by muse, mutect2, varscan2
- UBR5 | c.8268A>C p.P2756= | Silent (SNP) | VAF 529/764 reads (69%) | catalogued as COSV55280213, COSV55288707; called by muse, mutect2, varscan2
- ZIM3 | c.513C>T p.A171= | Silent (SNP) | VAF 94/220 reads (43%) | catalogued as COSV99517611; called by muse, mutect2
- ZNF280C | c.336T>A p.S112= | Silent (SNP) | VAF 139/695 reads (20%) | catalogued as COSV63969021; called by muse, mutect2, varscan2
